Gene-level copy-number profile of specimen HCM-BROD-0328-C15-85A from HCMI case HCM-BROD-0328-C15, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Esophagus, NOS; Age at diagnosis: 62.6 years (22,865 days).
Specimen HCM-BROD-0328-C15-85A: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: 3D Organoid; Preservation method: Frozen; Passage count: 4.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file f6ef75be-2663-482e-a53d-6a777871945b.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HCM-BROD-0328-C15-10B (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,721 have no estimate.
https://portal.gdc.cancer.gov/files/12a10c20-d12c-4230-92e8-3902cf59c9ee

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 513; copy number 1: 3,922; copy number 2: 14,778; copy number 3: 28,334; copy number 4: 7,889; copy number 5: 2,451; copy number 6: 751; copy number 7: 61; copy number 8: 195; copy number 10: 8.

Homozygous deletions (total copy number 0; autosomes only): 52 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:175,079,307–175,115,242, 1 gene (within-gene range 0–3): NAALADL2-AS3.
- chr4:49,486,926–49,589,529, 12 genes: AC119751.3, ANKRD20A17P, AC119751.5, AC119751.2, AC119751.8, AC119751.7, MTCO3P42, AC119751.1, AC119751.6, SNX18P24, AC119751.4, SNX18P25.
- chr11:41,993,381–42,253,721, 2 genes: LINC02745, LINC02740.
- chr18:23,992,773–26,099,226, 37 genes (within-gene range 0–2): TTC39C, TTC39C-AS1, AC090772.2, AC090772.1, RNU5A-6P, AC090772.4, CABYR, AC090772.3, OSBPL1A, RNA5SP452, Metazoa_SRP, RNU6-435P, MIR320C2, AC023983.1, AC023983.2, IMPACT, Y_RNA, AC007922.2, HRH4, AC007922.1, AC007922.3, EIF4A3P1, LINC01915, RAC1P1, PPIAP57, AC018697.1, LINC01894, WBP2P1, AC104961.1, ZNF521, AC105114.2, AC105114.1, AC110603.1, RN7SL97P, AC027229.1, SS18, RPS24P18.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 264 genes in 6 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:121,314,947–121,580,524, 8 genes, copy number 10: AC243994.1, SRGAP2-AS1, LINC02798, AL592494.1, MTIF2P1, AL592494.2, EMBP1, LINC01691.
- chr9:60,914,407–61,662,690, 16 genes, copy number 8: SPATA31A5, AL590491.1, FAM74A6, AL590491.2, AL590491.3, SPATA31A7, BX005040.3, BX005040.2, FAM74A4, BX005040.1, CNTNAP3C, RN7SL462P, AL935212.3, FAM242D, Y_RNA, AL935212.1.
- chr11:88,050,106–89,065,945, 12 genes, copy number 7–8: AP005436.3, AP005436.1, AP005436.2, Y_RNA, RAB38, AP001642.1, MIR3166, CTSC, GAPDHP70, GRM5-AS1, GRM5, RNU6-16P.
- chr14:30,734,926–41,604,988, 175 genes, copy number 7–8 (within-gene range 3–8) (broad region; genes not listed).
- chr18:21,242,242–21,929,094, 23 genes, copy number 7–8: GREB1L, AC015878.2, AC015878.1, AC011774.1, ESCO1, SNRPD1, ABHD3, AC106037.2, AC106037.3, MIR320C1, MIB1, AC106037.1, Y_RNA, RN7SL233P, SNORA73, MIR133A1HG, MIR133A1, MIR1-2, AC103987.1, AC103987.2, RNU6-1038P, AC103987.3, RNA5SP451.
- chr18:22,164,886–23,672,748, 30 genes, copy number 7–8: GATA6-AS1, GATA6, AC091588.1, RNU6-702P, AC091588.3, AC091588.2, AC027449.1, CTAGE1, ATP7BP1, RPS4XP18, RNU6-1032P, AC090912.1, AC090912.2, RBBP8, AC090912.3, UBE2CP2, MIR4741, RN7SL745P, Y_RNA, CABLES1, TMEM241, AC011731.1, RIOK3, Y_RNA, AC026634.1, RMC1, NPC1, Y_RNA, ANKRD29, RPS10P27.

Autosomal genes at a single copy (total copy number 1): 3,365. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
